Somatic mutation profile of tumor specimen HCM-CSHL-0056-C18-01B (aliquot HCM-CSHL-0056-C18-01B-01D-A78J-36) from HCMI case HCM-CSHL-0056-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.1 years (27,431 days).
Specimen HCM-CSHL-0056-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8943f056-43a6-4d78-a4f0-1a76dab03442.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0056-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0056-C18-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef383370-ff2a-4409-9611-71be0b3c81a2

The open-access MAF lists 204 somatic variants for this specimen: 143 protein-altering or splice-affecting, 40 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 40, Nonsense Mutation 13, Intron 8, RNA 5, Frame Shift Del 4, 3'Flank 3, In Frame Del 2, Splice Site 2, 5'Flank 2, Frame Shift Ins 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXT1 | c.2101C>T p.R701* | Nonsense Mutation (SNP) | VAF 13/154 reads (8%) | catalogued as rs1363815113, CM010236; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 35/301 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 144/471 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- NEB | c.11289+1G>A p.X3763_splice | Splice Site (SNP) | VAF 13/53 reads (25%) | catalogued as rs762278237, CS1413963, COSV51458885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PTPN11 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 237/710 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918457, CM021672, COSV61005439; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 18/139 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5069G>A p.R1690Q | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368756746; called by muse, mutect2, varscan2
- ANKRD6 | c.1736C>T p.S579L (on ENST00000339746 / NM_001242809.2; = p.S574L on NM_014942.4) | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs750495083; called by muse, mutect2, varscan2
- APC | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 39/95 reads (41%) | catalogued as CM930020, COSV57326188; called by muse, mutect2, varscan2
- APC | c.4230C>A p.C1410* | Nonsense Mutation (SNP) | VAF 38/106 reads (36%) | catalogued as COSV57322030; called by muse, mutect2, varscan2
- ASMTL | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs759594201; called by muse, mutect2, varscan2
- ATP8A2 | c.3463G>A p.V1155I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1056080465; called by muse, mutect2, varscan2
- ATP8B2 | c.1208C>T p.T403M (on ENST00000672630; = p.T370M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.394); catalogued as rs1050193940, COSV59247342; called by muse, mutect2
- BAP1 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56236367; called by muse, mutect2, varscan2
- CADPS | c.3385C>T p.R1129* | Nonsense Mutation (SNP) | VAF 69/314 reads (22%) | catalogued as rs748581222, COSV51867184, COSV51891180; called by muse, mutect2, varscan2
- CCDC62 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs755321849; called by muse, varscan2
- CDC42BPB | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs749711259, COSV63475201; called by muse, mutect2, varscan2
- CHRNB4 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs368785360; called by muse, mutect2, varscan2
- CNNM1 | c.1523G>T p.C508F | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768607238; called by muse, mutect2
- COL15A1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs145278600, COSV100898092; called by muse, mutect2, varscan2
- CPAMD8 | c.1990G>A p.A664T (on ENST00000651564; = p.A617T on NM_015692.5) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs568970755, COSV52236816; called by muse, mutect2, varscan2
- CSNK1A1L | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV65789716; called by muse, mutect2
- DPYD | c.2950G>A p.D984N | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs760235888, COSV100929521; called by muse, mutect2
- DSTYK | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs562238251; called by muse, mutect2, varscan2
- ELAPOR2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs374577797; called by muse, mutect2, varscan2
- FAM47A | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as rs1304387328, COSV60498436, COSV60500315; called by muse, mutect2, varscan2
- FLG | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.051); catalogued as rs547196696, COSV64246252; called by muse, mutect2
- FOXN3 | c.1339G>A p.E447K (on ENST00000261302; = p.E425K on NM_005197.4) | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs780839699, COSV54310401; called by muse, mutect2, varscan2
- FOXP1 | c.1568T>C p.F523S | Missense Mutation (SNP) | VAF 8/233 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559602593, COSV59543795; ClinVar: uncertain significance; called by muse, mutect2
- FUT2 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs776245547; called by muse, mutect2, varscan2
- GABBR1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1028329001; called by muse, mutect2
- GABRB2 | c.1191G>A p.T397= | Splice Region (SNP) | VAF 36/129 reads (28%) | catalogued as rs373911261; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GAL3ST3 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750515200, COSV61749073; called by muse, mutect2, varscan2
- GLRA1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.426); catalogued as rs561848502, COSV51007409; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- GRM6 | c.1268G>T p.C423F | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1217441736; called by muse, mutect2, varscan2
- HMCN1 | c.15545G>A p.R5182Q | Missense Mutation (SNP) | VAF 144/442 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs148826584; called by muse, mutect2, varscan2
- IGHE | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs375858136; called by muse, mutect2, varscan2
- IHO1 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368444069; called by muse, mutect2, varscan2
- IL17RA | c.1042G>C p.A348P | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60053612; called by muse, mutect2
- ITPRID1 | c.2122G>T p.V708L | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV60069988; called by muse, mutect2, varscan2
- JAKMIP1 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs781019554, COSV68955286; called by muse, mutect2, varscan2
- KLHL23 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752643631; called by muse, mutect2, varscan2
- KRT27 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs775693252; called by muse, mutect2, varscan2
- KSR2 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs71452606, COSV100195751; called by muse, mutect2
- LRP2 | c.13650G>T p.K4550N | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1160377420; called by muse, mutect2, varscan2
- LRP2 | c.8623C>T p.R2875C | Missense Mutation (SNP) | VAF 144/299 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1308246487, COSV55547020, COSV55551317; called by muse, mutect2, varscan2
- LRRTM4 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 91/332 reads (27%) | catalogued as COSV69138907; called by muse, mutect2, varscan2
- MARK4 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.397); catalogued as rs1039550856, COSV53464813; called by muse, mutect2, varscan2
- MLLT6 | c.990_992del p.S338del | In Frame Del (DEL) | VAF 16/126 reads (13%) | catalogued as rs749105834; called by pindel, varscan2
- MPPED1 | c.63C>A p.C21* | Nonsense Mutation (SNP) | VAF 45/129 reads (35%) | catalogued as rs780341898, COSV100501203; called by muse, mutect2, varscan2
- NEFL | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99648224; called by muse, mutect2, varscan2
- NLGN4X | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 210/306 reads (69%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); catalogued as rs373602022, COSV52014407; called by muse, mutect2, varscan2
- NMBR | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV57801456; called by muse, mutect2
- NRK | c.1886C>A p.P629H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs375577034; called by mutect2, varscan2
- OCM | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs376247775, COSV54194874; called by muse, mutect2
- OR2T33 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 109/565 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.187); catalogued as rs777287203, COSV100531481, COSV58816166; called by muse, mutect2, varscan2
- OR5T1 | c.823A>G p.S275G | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV57302939; called by muse, varscan2
- PARP8 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55855228; called by muse, mutect2, varscan2
- PCDHA11 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.192); catalogued as rs1554163444; called by muse, mutect2
- PCDHB2 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV52029306; called by mutect2, varscan2
- PCDHB2 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 81/239 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV50571098; called by muse, mutect2, varscan2
- PCDHGA5 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); catalogued as rs748996894, COSV53925357; called by muse, mutect2
- PDGFRA | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57271399, COSV57277919; called by muse, mutect2
- PDGFRA | c.2575G>A p.V859M | Missense Mutation (SNP) | VAF 119/342 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1060501520, COSV57265097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3CD | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs573872848, COSV63128470; called by muse, mutect2
- PRSS53 | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs200170110; called by muse, mutect2, varscan2
- RAX | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.461); catalogued as COSV56873999; called by muse, mutect2
- RRBP1 | c.3511C>T p.R1171W (on ENST00000377813 / NM_001365613.2; = p.R738W on NM_004587.3) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1374708828, COSV55698663; called by muse, mutect2, varscan2
- RTL1 | c.2581C>T p.R861C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1457336557; called by muse, mutect2, varscan2
- SERTAD2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1033460708; called by muse, mutect2
- SLC10A1 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 90/286 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200362742; called by muse, varscan2
- SLC29A4 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs557809993; called by muse, mutect2, varscan2
- SLC2A14 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV61588507; called by muse, mutect2, varscan2
- SLFNL1 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 14/224 reads (6%) | catalogued as rs371063765; called by muse, mutect2
- SND1 | c.2429G>A p.R810H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); catalogued as rs1341123138; called by mutect2, varscan2
- SPTA1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 129/355 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs370498187; called by muse, mutect2, varscan2
- TEX13C | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 90/150 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1423216462; called by muse, varscan2
- TFCP2L1 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs775890940; called by muse, mutect2, varscan2
- TOGARAM2 | c.2945C>T p.T982M | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs902779573, COSV65422215; called by muse, mutect2
- TTC30B | c.106G>C p.G36R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1262312485; called by muse, mutect2, varscan2
- UNC13D | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 79/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs150442758, COSV52888047; called by muse, mutect2, varscan2
- USP45 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139278154; called by muse, mutect2, varscan2
- ZNF502 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56074335; called by muse, mutect2, varscan2
- ZNF555 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs548518127; called by muse, mutect2
- ZNF629 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.235); catalogued as COSV52700305; called by muse, mutect2
- ZNF778 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs573000338, COSV60600736; called by muse, mutect2, varscan2
- ABI1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ACTN2 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 36/348 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACVR2A | c.1251_1253del p.E418del | In Frame Del (DEL) | VAF 36/191 reads (19%) | called by pindel, varscan2
- ACVR2A | c.1432_1435del p.R478Lfs*7 | Frame Shift Del (DEL) | VAF 86/311 reads (28%) | called by mutect2, pindel, varscan2
- ADAMTSL3 | c.1559T>G p.L520R | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ADGRF3 | c.1734G>A p.W578* (on ENST00000311519 / NM_001145168.1; = p.W379* on NM_153835.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- AGBL1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- AGER | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2
- ANKRD9 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- ASB3 | c.381del p.L128* | Frame Shift Del (DEL) | VAF 14/147 reads (10%) | called by mutect2, pindel
- AURKC | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 34/706 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- CCAR1 | c.1370_1371insC p.M457Ifs*7 | Frame Shift Ins (INS) | VAF 8/84 reads (10%) | called by mutect2, pindel, varscan2
- COBL | c.3093_3097dup p.S1033Tfs*34 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by mutect2, pindel
- COL6A3 | c.7636C>A p.Q2546K | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.839); called by muse, mutect2
- CRB1 | c.2399T>C p.I800T | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- DCLRE1B | c.1460G>A p.S487N | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ELP2 | c.761G>T p.R254I | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- ENTPD3 | c.951T>A p.Y317* | Nonsense Mutation (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- EPB41L2 | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ERBIN | c.1206+1G>A p.X402_splice | Splice Site (SNP) | VAF 51/143 reads (36%) | called by muse, mutect2, varscan2
- FAM184B | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- FEM1C | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FGFRL1 | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FOXF2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GUCY1A1 | c.52T>C p.S18P | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- HBM | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- HDAC1 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- HSD17B3 | c.294G>T p.R98S | Missense Mutation (SNP) | VAF 112/379 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ITPR2 | c.3381G>C p.E1127D | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNB2 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF2A | c.1316T>C p.F439S | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LONRF2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, varscan2
- NBEA | c.6794T>A p.L2265Q | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NEB | c.11914C>G p.L3972V | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- NEK5 | c.2088G>T p.K696N | Missense Mutation (SNP) | VAF 116/276 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NR5A1 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTN4 | c.1017T>A p.D339E | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2
- PARD6B | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 22/343 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- PARG | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 98/799 reads (12%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB7 | c.1601C>A p.T534K | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- PJA1 | c.1462G>A p.V488I (on ENST00000361478 / NM_145119.4; = p.V300I on NM_022368.5) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLCG2 | c.2512C>T p.Q838* | Nonsense Mutation (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- PLCH1 | c.1834del p.A612Pfs*34 (on ENST00000340059 / NM_001130960.2; = p.A624Pfs*34 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/138 reads (25%) | called by mutect2, pindel, varscan2
- PSAT1 | c.1094T>A p.L365* (on ENST00000376588 / NM_058179.4; = p.L319* on NM_021154.5) | Nonsense Mutation (SNP) | VAF 147/409 reads (36%) | called by muse, mutect2, varscan2
- PTX3 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- RHBDD3 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- SETD2 | c.4913A>C p.Q1638P | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD2 | c.913del p.T305Qfs*35 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by pindel, varscan2
- SNRNP200 | c.6038G>A p.R2013H | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, varscan2
- SPART | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- SYNE1 | c.12764A>T p.K4255I (on ENST00000367255 / NM_182961.4; = p.K4184I on NM_033071.3) | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- TTN | c.25434G>T p.Q8478H (on ENST00000591111; = p.Q7551H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/142 reads (44%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS18 | c.1970G>A p.G657E | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- VSTM2A | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- XKR6 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- XPNPEP3 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- ZNF93 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 106/477 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.499); called by muse, varscan2
- AC100868.1 | c.1026C>T p.V342= | Silent (SNP) | VAF 62/147 reads (42%) | catalogued as rs368039478; called by muse, mutect2, varscan2
- BTBD1 | c.30G>A p.G10= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- CACNA1D | c.669C>T p.G223= | Silent (SNP) | VAF 86/157 reads (55%) | catalogued as rs756461282, COSV55442986; called by muse, mutect2, varscan2
- CASZ1 | c.1128C>T p.Y376= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs535551834, COSV100681306, COSV100682140; called by muse, mutect2, varscan2
- CDH5 | c.2253C>T p.S751= | Silent (SNP) | VAF 68/227 reads (30%) | catalogued as COSV58515638; called by muse, mutect2, varscan2
- CHD2 | c.5058C>T p.S1686= | Silent (SNP) | VAF 25/346 reads (7%) | catalogued as rs199851404; ClinVar: likely benign; called by muse, mutect2
- COL27A1 | c.1077C>T p.I359= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV61928911; called by muse, mutect2, varscan2
- CYRIA | c.411T>C p.F137= | Silent (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- ERICH2 | c.438C>T p.D146= | Silent (SNP) | VAF 66/360 reads (18%) | catalogued as rs935703660; called by muse, mutect2, varscan2
- FAM110B | c.522G>A p.P174= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs183366212, COSV64063953; called by muse, mutect2, varscan2
- FBXO7 | c.1113G>T p.L371= | Silent (SNP) | VAF 46/470 reads (10%) | called by muse, mutect2
- GPHN | c.1203G>A p.Q401= (on ENST00000315266 / NM_001377519.1; = p.Q434= on NM_020806.5) | Silent (SNP) | VAF 14/358 reads (4%) | called by muse, mutect2
- INSYN1 | c.532C>A p.R178= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- LAIR1 | c.840G>A p.T280= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs746249343, COSV57306180; called by muse, mutect2, varscan2
- LAMA3 | c.8592C>T p.I2864= (on ENST00000313654 / NM_198129.4; = p.I1255= on NM_000227.6) | Silent (SNP) | VAF 124/382 reads (32%) | catalogued as rs779758375, COSV52535196; called by muse, mutect2, varscan2
- MIDN | c.1281C>T p.S427= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as rs368362828; called by muse, mutect2
- MUC16 | c.15840G>A p.S5280= | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- MYH6 | c.1809C>T p.N603= | Silent (SNP) | VAF 19/269 reads (7%) | catalogued as rs186134696; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- NPHS1 | c.3579C>T p.Y1193= | Silent (SNP) | VAF 73/182 reads (40%) | catalogued as rs747950877, COSV62286104; called by muse, mutect2, varscan2
- PCDHA1 | c.201G>A p.A67= | Silent (SNP) | VAF 86/262 reads (33%) | catalogued as rs376604489; called by muse, mutect2, varscan2
- PCDHA13 | c.183G>A p.P61= | Silent (SNP) | VAF 12/300 reads (4%) | catalogued as COSV56493090; called by muse, mutect2
- PCDHB4 | c.2031G>A p.P677= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as rs151032773; called by muse, mutect2
- PDE1C | c.1737A>G p.T579= | Silent (SNP) | VAF 134/439 reads (31%) | catalogued as rs771548329; called by muse, mutect2, varscan2
- PFAS | c.1854G>A p.P618= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs146140082; called by muse, mutect2, varscan2
- PGBD1 | c.1416T>C p.H472= | Silent (SNP) | VAF 38/411 reads (9%) | catalogued as rs1259371735; called by muse, mutect2
- PIGW | c.1293C>T p.A431= | Silent (SNP) | VAF 8/192 reads (4%) | catalogued as rs138225253; called by muse, mutect2
- POU3F2 | c.558C>T p.G186= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- PTCHD3 | c.699C>T p.D233= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as rs1260956905, COSV71257235; called by muse, mutect2, varscan2
- RFX3 | c.1713G>A p.A571= | Silent (SNP) | VAF 20/410 reads (5%) | catalogued as rs757709200, COSV56525101; called by muse, mutect2
- RYR1 | c.4743C>T p.S1581= | Silent (SNP) | VAF 88/255 reads (35%) | catalogued as rs370041876; called by muse, mutect2, varscan2
- SLC35G4 | c.327G>T p.L109= | Silent (SNP) | VAF 72/226 reads (32%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.969C>T p.V323= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as rs866381547, COSV65805356; called by muse, mutect2, varscan2
- SREBF1 | c.279G>T p.A93= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- ST3GAL1 | c.669G>A p.T223= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs774739947; called by muse, mutect2
- TNFAIP2 | c.1449C>T p.T483= | Silent (SNP) | VAF 96/275 reads (35%) | called by muse, mutect2, varscan2
- TOB1 | c.912T>C p.S304= | Silent (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- UPP1 | c.798C>T p.A266= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs1044090475, COSV57977025; called by muse, mutect2, varscan2
- VCX3A | c.360G>A p.V120= | Silent (SNP) | VAF 88/488 reads (18%) | called by muse, varscan2
- WWP1 | c.714C>T p.A238= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as rs769578841, COSV99616756; called by muse, mutect2, varscan2
- ZFHX4 | c.7110G>A p.T2370= | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as COSV50534522, COSV99254900; called by muse, mutect2, varscan2
- AGPAT5 | c.219+101C>T | Intron (SNP) | VAF 11/95 reads (12%) | catalogued as rs1294400049; called by muse, mutect2, varscan2
- AKR1B1P6 | n.161G>T | RNA (SNP) | VAF 9/191 reads (5%) | called by muse, mutect2
- ALG2 | c.*145A>G | 3'UTR (SNP) | VAF 104/380 reads (27%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.244G>A | RNA (SNP) | VAF 98/283 reads (35%) | catalogued as rs770217898; called by muse, mutect2, varscan2
- DPY19L2P2 | n.587A>G | RNA (SNP) | VAF 10/195 reads (5%) | called by muse, mutect2
- DUSP22 | c.508+48C>T | Intron (SNP) | VAF 36/234 reads (15%) | catalogued as rs747000459; called by muse, mutect2, varscan2
- FCER2 | c.22+342T>C | Intron (SNP) | VAF 21/204 reads (10%) | called by muse, mutect2, varscan2
- GUSBP3 | chr5:69635557 G>C | 3'Flank (SNP) | VAF 23/245 reads (9%) | catalogued as rs1275922109; called by muse, mutect2
- HAS1 | c.-33G>A | 5'UTR (SNP) | VAF 55/183 reads (30%) | called by muse, mutect2, varscan2
- IFT81 | c.1188+4840G>A | Intron (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- KLK1 | chr19:50818499 del C | 3'Flank (DEL) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- NKX3-2 | chr4:13546954 C>T | 5'Flank (SNP) | VAF 15/210 reads (7%) | called by muse, mutect2
- PACRG | c.614-67727C>A | Intron (SNP) | VAF 20/92 reads (22%) | catalogued as COSV61303693; called by muse, mutect2, varscan2
- PARGP1 | n.1023G>A | RNA (SNP) | VAF 91/471 reads (19%) | catalogued as rs1333800495; called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156435 G>T | 3'Flank (SNP) | VAF 20/214 reads (9%) | called by muse, mutect2
- PDE6H | c.-18C>T | 5'UTR (SNP) | VAF 11/156 reads (7%) | catalogued as rs769920359; called by muse, mutect2
- PNP | c.285+49A>T | Intron (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- POM121L4P | n.140C>A | RNA (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- SHOX2 | c.346+566G>A | Intron (SNP) | VAF 22/272 reads (8%) | catalogued as rs770972796; called by muse, mutect2
- TRIP4 | chr15:64387449 C>A | 5'Flank (SNP) | VAF 47/170 reads (28%) | called by muse, mutect2, varscan2
- TRPM3 | c.184-256801C>T | Intron (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2, varscan2
